Somatic mutation profile of tumor specimen TCGA-EM-A4FH-01A (aliquot TCGA-EM-A4FH-01A-11D-A257-08) from TCGA case TCGA-EM-A4FH, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 69.8 years (25,500 days).
Specimen TCGA-EM-A4FH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a0e3941-c662-463a-85b6-e272899ffecb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A4FH-10A (Blood Derived Normal), aliquot TCGA-EM-A4FH-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91668649-15f8-49a3-ab28-1a6b0be878cd

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNST | c.1123A>T p.T375S | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV100829980; called by muse, mutect2, varscan2
- EFCAB14 | c.1387C>A p.L463I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); catalogued as COSV100485947; called by muse, mutect2, varscan2
- RPS2 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99238666; called by muse, mutect2, varscan2
- NOMO3 | c.908A>T p.D303V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- CXCL3 | c.147G>A p.L49= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV99932759; called by muse, mutect2
- EFCAB14 | c.1386C>T p.S462= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs935453165, COSV100485948; called by muse, mutect2, varscan2
- RBM10 | c.987C>A p.S329= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100237196; called by muse, mutect2
- CDKL1 | c.171+17298C>T | Intron (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
